Gene-level copy-number profile of tumor specimen TCGA-OY-A56Q-01A from TCGA case TCGA-OY-A56Q, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIA; Tumor grade: G3; Age at diagnosis: 78.4 years (28,623 days).
Specimen TCGA-OY-A56Q-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-OV.5e52d425-00fa-4cd2-a278-8e298d333ce1.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-OY-A56Q-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 813 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/48feac12-00fd-4a90-9dd2-feaa2f307dc1

Most common (modal) total copy number across autosomal genes: 5 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 2,421; copy number 2: 3,572; copy number 3: 11,644; copy number 4: 7,163; copy number 5: 11,739; copy number 6: 9,844; copy number 7: 7,056; copy number 8: 3,334; copy number 9: 1,997; copy number 10: 353; copy number 11: 393; copy number 12: 54; copy number 13: 46; copy number 16: 87; copy number 18: 45; copy number 26: 62.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-OY-A56Q-01A-11D-A402-01): tumor purity 0.98, ploidy 5.02, whole-genome doublings 2.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 11, i.e. more than twice the modal value of 5; autosomes only): 687 genes in 11 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:22,381,819–23,641,592, 12 genes, copy number 11–18: HMGB1P5, AC092421.1, AC114477.1, RANP7, SALL4P5, RPL24P7, UBE2E2-AS1, UBE2E2, Y_RNA, AC121251.1, RNU6-922P, RNU6-788P.
- chr3:67,225,464–68,545,621, 9 genes, copy number 11 (within-gene range 9–11): MIR4272, AC114401.1, SUCLG2, NDUFB4P1, SUCLG2-AS1, TAFA1, COPS8P2, AC107626.1, AC104167.1.
- chr6:9,124,221–9,161,777, 1 gene, copy number 11: AL137220.1.
- chr6:19,143,695–19,839,080, 8 genes, copy number 11 (within-gene range 8–11): AL589647.1, AL357052.1, LNC-LBCS, RPL5P20, RNA5SP205, KRT18P38, UQCRFS1P3, RNU6-801P.
- chr6:46,096,004–50,181,007, 63 genes, copy number 11 (within-gene range 8–11) (broad region; genes not listed).
- chr6:54,307,859–55,282,620, 11 genes, copy number 11 (within-gene range 9–11): TINAG, TINAG-AS1, CLNS1AP1, RPL10P10, RPSAP44, KRASP1, RNU6-1023P, AL512363.1, FAM83B, AL049555.1, HCRTR2.
- chr12:16,989,126–18,648,416, 17 genes, copy number 11 (within-gene range 9–11): SKP1P2, EEF1A1P16, AC092793.1, RNU6-837P, AC092110.1, RPL7P40, PSMC1P8, TIMM17BP1, AC048352.1, LINC02378, MIR3974, Y_RNA, RERGL, PIK3C2G, NDFIP1P1, AC092851.1, ZKSCAN7P1.
- chr19:11,639,754–17,813,576, 360 genes, copy number 11–16 (within-gene range 2–16) (broad region; genes not listed).
- chr19:35,487,324–36,054,739, 53 genes, copy number 12: KRTDAP, DMKN, SBSN, GAPDHS, TMEM147-AS1, TMEM147, ATP4A, AD000090.1, PMIS2, LINC01766, AC002115.1, HAUS5, RBM42, ETV2, COX6B1, UPK1A, UPK1A-AS1, TYMSP2, ZBTB32, KMT2B, IGFLR1, AD000671.2, U2AF1L4, PSENEN, AD000671.1, AD000671.3, LIN37, AC002398.2, HSPB6, PROSER3, AC002398.1, ARHGAP33, LINC01529, PRODH2, NPHS1, KIRREL2, APLP1, RN7SL402P, NFKBID, AD000864.1, HCST, TYROBP, LRFN3, AF038458.3, AF038458.1, AF038458.2, SDHAF1, SYNE4, AC002116.1, ALKBH6, AC002116.2, CLIP3, THAP8.
- chr19:36,070,239–36,071,070, 1 gene, copy number 12: AD000813.1.
- chr19:43,166,256–45,873,797, 152 genes, copy number 13–26 (within-gene range 9–26) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 0. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
